Gene-level copy-number profile of tumor specimen TCGA-X6-A7W8-01A from TCGA case TCGA-X6-A7W8, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Fibromyxosarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-X6-A7W8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.6592905d-2b60-4612-b3a4-ce935577de7b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-X6-A7W8-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f1ecf94d-d985-482e-b64b-4a7b0f41d6aa

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 85; copy number 1: 2,752; copy number 2: 26,421; copy number 3: 21,552; copy number 4: 5,642; copy number 5: 1,878; copy number 6: 677; copy number 7: 229; copy number 8: 394; copy number 9: 70; copy number 10: 57; copy number 11: 3; copy number 40: 50; copy number 52: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-X6-A7W8-01A-21D-A350-01): tumor purity 0.67, ploidy 2.65, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 85 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:150,584–488,512, 16 genes: AC131281.2, WBP1LP3, OR4F21, SEPTIN14P8, AC131281.1, RPL23AP53, ZNF596, AC004908.2, AC004908.1, AC004908.3, AC136777.2, AC136777.1, FAM87A, FBXO25, AC083964.1, AC083964.2.
- chr8:1,971,153–2,165,552, 8 genes: AC019257.1, KBTBD11-OT1, KBTBD11, AC019257.2, AC245164.1, MYOM2, MIR7160, AC245164.2.
- chr13:48,296,162–49,444,064, 25 genes: RB1-DT, RB1, PPP1R26P1, PCNPP5, AL392048.1, LPAR6, Metazoa_SRP, RCBTB2, AL157813.2, AL157813.1, LINC01077, LINC00462, CYSLTR2, PSME2P2, AL161421.1, FNDC3A, RNU6-60P, RAD17P2, RNY3P2, COX7CP1, OGFOD1P1, MLNR, AL137000.1, CDADC1, CAB39L.
- chr13:93,032,972–94,408,020, 9 genes (within-gene range 0–1): LINC00363, AL354811.2, AL354811.1, GPC6, AL160159.1, HNRNPA1P29, GPC6-AS2, RNA5SP35, GPC6-AS1.
- chr18:11,689,264–11,885,685, 1 gene (within-gene range 0–1): GNAL.
- chr18:11,810,406–12,223,539, 26 genes: AP005137.1, CHMP1B, CHMP1B-AS1, AP005137.2, MPPE1, AP001269.4, AP001269.2, AP001269.3, IMPA2, AP001269.1, AP001542.3, AP001542.1, AP001542.2, AP002414.1, AP002414.4, AP002414.2, AP002414.5, AP002414.3, ANKRD62, RNU6-324P, SDHDP1, PMM2P2, AP005264.5, AP005264.3, AP005264.4, CCDC58P3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,973 genes in 46 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:117,754,139–127,931,440, 134 genes, copy number 5 (broad region; genes not listed).
- chr3:110,527,482–111,665,750, 12 genes, copy number 5 (within-gene range 3–5): AC117430.1, RNU6ATAC15P, RPSAP29, Y_RNA, NECTIN3-AS1, NECTIN3, CD96, AC092916.1, ATP6V0CP2, AC092916.2, ZBED2, NT5C3AP2.
- chr5:58,198–2,184,820, 78 genes, copy number 5–8 (broad region; genes not listed).
- chr5:12,297,399–16,192,709, 42 genes, copy number 5–7: RNU6-679P, AC106771.1, LINC01194, AC106794.2, AC106794.1, LINC02220, AC016553.1, RPS23P5, NENFP3, AC016546.1, DNAH5, AC016576.1, TRIO, AC016549.1, OTULINL, AC010627.1, CCT6P2, EEF1A1P13, AC010491.1, OTULIN, ANKH, AC010491.2, RBBP4P1, MIR4637, AC016575.1, UQCRBP3, HNRNPKP5, SEPHS2P1, AC016575.2, U8, LINC02149, MARK2P5, AC114964.2, AC114964.1, FBXL7, CTD-2350J17.1, MIR887, RNA5SP178, MARCHF11, MARCHF11-AS1, AC092335.1, NACAP6.
- chr5:18,886,622–19,234,487, 8 genes, copy number 9: UBE2V1P12, AC025768.1, AC114981.1, Metazoa_SRP, AC106744.1, AC106744.2, RPL32P14, HSPD1P15.
- chr6:162,568,379–163,315,492, 5 genes, copy number 5 (within-gene range 4–5): KRT8P44, PACRG, AL590286.1, AL590286.2, PACRG-AS2.
- chr7:41,960,949–42,264,100, 2 genes, copy number 5 (within-gene range 4–5): GLI3, HMGN2P30.
- chr7:45,460,712–48,029,119, 40 genes, copy number 6: AC073325.1, AC073325.2, ADCY1, SEPTIN7P2, GTF2IP13, RNU6-241P, CICP20, AC096582.1, AC096582.2, RNU6-326P, CCDC201, IGFBP1, IGFBP3, AC073115.2, AC073115.1, FTLP15, TTC4P1, ZNF619P1, AC023669.1, AC023669.2, AC004869.2, AC004869.1, HMGN1P19, AC011294.1, EPS15P1, AC004870.4, AC004870.2, AC004870.3, MRPL42P4, AC004870.1, AC087175.1, TNS3, LINC01447, C7orf65, PKD1L1, LINC00525, C7orf69, AC069282.1, HUS1, SUN3.
- chr8:114,282,067–115,809,673, 5 genes, copy number 11–52 (within-gene range 4–52): AC064802.1, AC025881.1, CARS1P2, TRPS1, AF178030.1.
- chr8:139,460,062–140,638,283, 14 genes, copy number 5: AC087354.1, AC090093.1, KCNK9, TRAPPC9, AC021744.1, C8orf17, AC040978.1, PEG13, AC107375.1, CHRAC1, AGO2, AC067931.1, AC067931.2, ERICD.
- chr8:143,039,209–145,066,685, 134 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr9:3,526,723–6,066,714, 60 genes, copy number 5 (within-gene range 3–5): RFX3-AS1, AL354977.2, AL354977.1, GLIS3, AL137071.1, GLIS3-AS1, AL359095.1, AL162419.1, RNU6-694P, SLC1A1, SPATA6L, AL136231.1, PLPP6, CDC37L1-DT, CDC37L1, AK3, AL353151.2, ECM1P1, AL353151.1, RCL1, KLF4P1, MIR101-2, AL158147.1, HNRNPA1P41, JAK2, CSNK1G2P1, PDSS1P1, MTND6P5, MTND1P11, MTCO1P11, MTCO2P11, MTATP6P11, MTCO3P11, MTND4P14, MTND5P14, TCF3P1, IGHEP2, INSL6, AL133547.1, INSL4, RLN2, HMGN2P31, RLN1, AL135786.2, AL135786.1, PLGRKT, RNF152P1, CD274, AL162253.2, PDCD1LG2, AL162253.1, RIC1, AL136980.1, ERMP1, AK4P4, KIAA2026, MLANA, MIR4665, RANBP6, AL162384.1.
- chr9:6,902,670–13,279,692, 41 genes, copy number 5–6 (within-gene range 4–6): AL513412.1, AL161443.1, AL157703.1, RPL4P5, PPIAP33, AL354694.1, DMAC1, AL135923.2, AL135923.1, PTPRD, AL583805.2, AL583805.1, RNU7-185P, PTPRD-AS1, AL596451.1, RPS26P3, RN7SL5P, AL513422.1, AL135790.2, PTPRD-AS2, AL135790.1, AL161788.1, IMP3P1, AL162413.1, AKAP8P1, AL451129.1, AL355672.1, AL592227.1, AL353595.1, AL589678.1, JKAMPP1, RNU2-47P, TYRP1, LURAP1L-AS1, RN7SL849P, LURAP1L, Y_RNA, AL161449.2, PRDX1P1, AL161449.1, MPDZ.
- chr9:26,066,675–37,090,928, 259 genes, copy number 5 (broad region; genes not listed).
- chr10:274,190–3,047,083, 38 genes, copy number 5–9: DIP2C, RNA5SP298, RN7SL754P, AL669841.1, AL358216.1, MIR5699, PRR26, AL157709.1, LARP4B, AL359878.2, AL359878.1, GTPBP4, IDI2, IDI2-AS1, IDI1, WDR37, LINC00200, ADARB2, AL392083.2, AL392083.1, AL513304.1, ADARB2-AS1, AL355597.1, LINC00700, AL441943.1, MIR6072, RNU6-889P, AL441943.2, LINC02662, RNU6-576P, LINC00701, LINC02645, AL713851.2, AL713851.1, AL355361.1, AC026396.1, AL731533.1, AL731533.3.
- chr11:83,455,012–85,627,922, 1 gene, copy number 6 (within-gene range 3–6): DLG2.
- chr11:83,789,977–87,330,052, 56 genes, copy number 6: AP002370.1, LDHAL6DP, HNRNPA1P72, AP000852.1, AP001825.1, AP001825.2, AP001825.3, AP000857.2, AP000857.1, HNRNPCP6, AP002803.1, AP003035.1, RNU6-1292P, TMEM126B, TMEM126A, CREBZF, CCDC89, SYTL2, AP000974.1, CCDC83, AP003128.1, SLC25A1P1, PICALM, RNU6-560P, LINC02695, FNTAP1, Metazoa_SRP, EED, MIR6755, AP003084.1, SETP17, HIKESHI, RN7SL225P, CCDC81, AP001831.1, PTP4A1P6, AP001148.1, ME3, AP003059.1, AP003059.2, PRSS23, MOB4P2, OR7E13P, AP000654.1, OR7E2P, AP001528.1, AP001528.2, FZD4, FZD4-DT, HNRNPCP8, TMEM135, XIAPP2, AP002967.1, AP001102.1, AP000811.1, PSMA2P1.
- chr12:73,115,957–74,402,600, 14 genes, copy number 6 (within-gene range 3–6): AC090503.2, LINC02444, AC090503.1, AC087879.1, RNU6-1012P, LINC02445, U8, LINC02882, AC136188.1, LINC02394, AC090502.3, AC090502.2, AC090502.1, VENTXP3.
- chr13:25,246,201–27,017,909, 29 genes, copy number 6: MTMR6, AL590787.1, NUP58, ELOBP1, ATP8A2, RNU6-78P, AL157366.1, RN7SL741P, RNY1P3, SHISA2, LINC00415, ATP8A2P3, PRUNEP1, RNF6, AL138966.2, AL138966.1, THAP12P6, CDK8, AL159159.1, AL353789.1, WASF3, RPS3AP44, WASF3-AS1, AL159978.1, GPR12, FGFR1OP2P1, AL160035.1, RPS21P8, RPS20P32.
- chr13:27,077,218–27,077,962, 1 gene, copy number 6: AL158062.1.
- chr13:39,209,116–40,666,641, 14 genes, copy number 5 (within-gene range 3–5): LHFPL6, COG6, MIR4305, RNY4P14, CDKN2AIPNLP3, AZU1P1, SNORD116, LINC00598, LINC00332, RPL17P51, RNY3P9, RN7SKP2, AL133318.1, FOXO1.
- chr13:112,313,467–113,928,991, 50 genes, copy number 40: LINC01043, LINC01044, SPACA7, TUBGCP3, AL139384.2, ATP11AUN, AL139384.1, ATP11A, ATP11A-AS1, AL356752.1, MCF2L, AL356740.1, MCF2L-AS1, AL356740.2, AL356740.3, F7, F10, F10-AS1, KARS1P2, AL137002.2, PROZ, AL137002.1, PCID2, CUL4A, MIR8075, LDHBP1, LAMP1, GRTP1, AL136221.1, GRTP1-AS1, ADPRHL1, DCUN1D2, DCUN1D2-AS, RNU1-16P, TMCO3, AL442125.2, AL442125.1, TFDP1, ATP4B, GRK1, LINC00552, TMEM255B, GAS6-AS1, GAS6, GAS6-DT, BX072579.1, LINC00454, BX072579.2, LINC00452, LINC00565.
- chr14:29,576,479–30,191,898, 1 gene, copy number 5 (within-gene range 3–8): PRKD1.
- chr14:29,928,445–32,837,684, 56 genes, copy number 5–8 (within-gene range 3–8): AL355053.1, AL133372.3, AL133372.2, AL133372.1, AL079305.1, G2E3-AS1, AL117355.1, SYF2P1, G2E3, SCFD1, UBE2CP1, AL121852.1, RPL12P5, AL049830.2, AL049830.1, COCH, AL049830.3, STRN3, HIGD1AP17, MIR624, AL049830.4, AP4S1, HECTD1, RPL21P5, RNU6-541P, Y_RNA, AL136418.1, Y_RNA, HEATR5A, ATP5MC1P2, AL139353.1, AL139353.2, DTD2, AL163973.1, GPR33, NUBPL, AL163973.3, AL163973.2, RNU6-602P, RNU6-455P, AL355112.1, LINC02313, AL352984.2, AL352984.1, ARHGAP5-AS1, ARHGAP5, AL161665.1, AL161665.2, RNU6-7, RNU6-8, AL136298.2, KIAA1143P1, AKAP6, AL136298.1, RN7SL660P, MTCO1P2.
- chr16:11,555–17,933,275, 672 genes, copy number 5 (broad region; genes not listed).
- chr17:7,717,354–21,594,180, 526 genes, copy number 5–10 (broad region; genes not listed).
- chr17:40,473,554–40,665,181, 9 genes, copy number 5: AC018629.1, TNS4, AC004585.1, CCR7, AC004585.2, SMARCE1, AC073508.2, AC073508.3, KRT222.
- chr17:44,557,484–44,797,783, 14 genes, copy number 5: FZD2, AC091152.3, SMCO4P1, LINC01180, MEIOC, CCDC43, AC091152.2, AC091152.4, DBF4B, RN7SL819P, AC091152.1, ADAM11, AC005180.2, AC005180.1.
- chr17:46,372,855–46,911,512, 11 genes, copy number 5: NSFP1, RDM1P2, LRRC37A2, ARL17A, RN7SL199P, FAM215B, NSF, RPS7P11, WNT3, WNT9B, LINC01974.
- chr17:73,334,384–73,644,445, 2 genes, copy number 6 (within-gene range 4–6): SDK2, AC124804.1.
- chr17:74,466,399–74,747,335, 12 genes, copy number 6 (within-gene range 4–6): CD300A, CD300LB, CD300C, AC079325.1, CD300H, CD300LD, C17orf77, AC064805.1, CD300E, AC064805.2, RAB37, CD300LF.
- chr18:12,230,411–13,915,707, 51 genes, copy number 5–6 (within-gene range 4–6): AP005264.2, PPIAP56, CIDEA, AP005264.6, AP005264.1, RNU6-170P, TUBB6, AFG3L2, RNU7-129P, PRELID3A, AP001029.1, AP001029.2, SPIRE1, AP001029.3, PSMG2, CEP76, AP005482.2, AP005482.1, LINC01882, Y_RNA, PTPN2, STK25P1, EIF4A2P1, SEH1L, AP002449.1, CEP192, AP001357.2, AP001357.1, AP001198.2, AP001198.1, LDLRAD4, AP002505.1, C18orf15, AP002505.3, AP002505.2, AP002439.1, LDLRAD4-AS1, MIR5190, AP005131.5, AP005131.4, AP005131.2, AP005131.1, AP005131.3, MIR4526, AP001010.1, FAM210A, AP001525.1, RN7SL362P, RNMT, MC5R, MC2R.
- chr18:14,053,951–15,330,282, 52 genes, copy number 6: AC006557.5, ZNF519, AC006557.4, AC006557.1, AC006557.3, FRG2LP, AC006557.2, NF1P5, ANKRD20A5P, RNU6-316P, RHOT1P1, AP005212.4, AP005212.2, CYP4F35P, AP005212.3, AP005212.1, TERF1P2, FEM1AP2, AP006261.1, LONRF2P1, CXADRP3, GRAMD4P7, POTEC, RNU6-1021P, OR4K7P, OR4K8P, SNX19P3, VN1R74P, GTF2IP8, ANKRD30B, RNU6-1210P, AP006565.1, MIR3156-2, LINC01906, FGF7P1, AP005121.1, LINC01443, LINC01444, AP005121.2, AP005242.4, AP005242.2, AP005242.3, AP005242.1, AP005242.5, AP005901.2, AP005901.6, AP005901.5, AP005901.3, BNIP3P3, AP005901.4, AP005901.1, RNU6-721P.
- chr20:2,864,184–4,823,608, 56 genes, copy number 5 (within-gene range 1–5): PTPRA, GNRH2, MRPS26, OXT, AVP, RN7SL555P, UBOX5-AS1, UBOX5, FASTKD5, LZTS3, DDRGK1, ITPA, SLC4A11, AL109976.1, C20orf194, RNU6-1019P, UBE2V1P1, U3, AL117334.1, AL353193.1, ATRN, SF3A3P1, GFRA4, ADAM33, SIGLEC1, HSPA12B, C20orf27, SPEF1, CENPB, CDC25B, LINC01730, AL109804.1, AP5S1, MAVS, PANK2-AS1, PANK2, MIR103A2, MIR103B2, AL031670.1, RNF24, FTLP3, RPL21P2, AL356414.1, SMOX, LINC01433, ADRA1D, AL139350.1, AL121781.1, AL121916.1, RPS4XP2, PRNP, PRND, PRNT, IDI1P3, AL133396.1, RASSF2.
- chr20:31,944,337–34,540,748, 91 genes, copy number 6 (within-gene range 2–6) (broad region; genes not listed).
- chr20:34,741,401–35,742,312, 44 genes, copy number 6: AL109824.1, HMGB3P1, GGT7, ACSS2, GSS, MYH7B, MIR499A, MIR499B, TRPC4AP, RNU6-407P, EDEM2, AL135844.1, PROCR, AL356652.1, RNA5SP483, MMP24OS, MT1P3, MMP24, AL121753.2, AL121753.1, EIF6, FAM83C-AS1, FAM83C, UQCC1, GDF5-AS1, GDF5, MIR1289-1, CEP250, CEP250-AS1, FO393401.1, C20orf173, ERGIC3, RPL36P4, FER1L4, RPL37P1, SPAG4, CPNE1, AL109827.1, RN7SKP271, RNU6-759P, RBM12, NFS1, ROMO1, RBM39.
- chr20:50,081,124–60,083,872, 191 genes, copy number 6–8 (broad region; genes not listed).
- chr20:61,077,224–62,296,213, 19 genes, copy number 8 (within-gene range 4–8): AL121910.1, LINC01718, CDH4, AL365229.1, BX640515.1, AL160412.1, AL162457.1, AL162457.2, TAF4, MIR1257, AL137077.1, MIR3195, AL137077.2, LSM14B, PSMA7, SS18L1, MTG2, HRH3, OSBPL2.
- chr21:10,328,411–13,980,437, 45 genes, copy number 5 (within-gene range 4–5): AP003900.1, VN1R7P, AF254983.2, BAGE2, AF254983.1, TPTE, CYCSP41, SLC25A15P4, AF254982.1, IGHV1OR21-1, AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1, AJ239318.1, FGF7P2, ANKRD30BP1, MIR3156-3, GTF2IP2, VN1R8P, LINC01674, SNX19P1, OR4K11P, OR4K12P, POTED, RNU6-286P, MIR3118-1, AL050303.2, GRAMD4P1, CXADRP1, AL050303.3, LONRF2P5, MIR8069-2, FEM1AP1, AL050303.1, TERF1P1, FAM207CP, GXYLT1P2, CNN2P7, ZNF114P1, CYP4F29P, SNX18P13, ANKRD20A11P, RHOT1P2.
- chr21:22,205,192–28,228,667, 78 genes, copy number 6–9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,397. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
